Somatic mutation profile of tumor specimen TCGA-13-0888-01A (aliquot TCGA-13-0888-01A-01W-0420-08) from TCGA case TCGA-13-0888, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 78.0 years (28,498 days).
Specimen TCGA-13-0888-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eda8e587-bcf9-4012-855f-35fca16767bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0888-10A (Blood Derived Normal), aliquot TCGA-13-0888-10A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e5aad6c-0122-42d6-a5f2-1e7b1218497e

The open-access MAF lists 202 somatic variants for this specimen: 142 protein-altering or splice-affecting, 56 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 56, Nonsense Mutation 8, Frame Shift Ins 3, Splice Site 3, Intron 2, Frame Shift Del 2, RNA 1, In Frame Del 1, 3'UTR 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.673-2A>G p.X225_splice | Splice Site (SNP) | VAF 394/475 reads (83%) | hotspot (GDC flag); catalogued as rs1555525585, CS109519, COSV52669186, COSV52682653, COSV52687702; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- TREX1 | c.144dup p.T49Hfs*53 (on ENST00000625293 / NM_033629.6; = p.T39Hfs*53 on NM_007248.5) | Frame Shift Ins (INS) | VAF 22/182 reads (12%) | catalogued as rs748914604; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA10 | c.4148A>C p.Q1383P | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV99288892; called by muse, mutect2, varscan2
- ABCD2 | c.1032A>T p.E344D | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58050963; called by muse, mutect2, varscan2
- ABCF1 | c.1273G>A p.A425T (on ENST00000326195 / NM_001025091.2; = p.A387T on NM_001090.3) | Missense Mutation (SNP) | VAF 120/403 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.826); catalogued as COSV100400917; called by muse, mutect2, varscan2
- ACSS3 | c.296C>G p.S99W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs747945335, COSV99699117; called by muse, mutect2, varscan2
- ACTR10 | c.544C>G p.Q182E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV99581246; called by muse, mutect2, varscan2
- ALG1 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV99275854; called by muse, mutect2, varscan2
- AMBRA1 | c.2919C>A p.H973Q (on ENST00000458649 / NM_001367468.1; = p.H883Q on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.986); catalogued as COSV100094532; called by muse, mutect2, varscan2
- ANGPTL2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV99401981; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3563A>T p.K1188I | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51850573, COSV99783772; called by muse, mutect2, varscan2
- ANKRD13C | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99257221; called by muse, mutect2, varscan2
- APBA2 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as rs145494651; called by muse, mutect2, varscan2
- ATP8B2 | c.1249G>A p.G417S (on ENST00000672630; = p.G384S on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100528099; called by muse, mutect2, varscan2
- ATXN3 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 67/302 reads (22%) | catalogued as COSV100515425; called by muse, mutect2, varscan2
- BARD1 | c.1850C>T p.T617I | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99639080; called by muse, mutect2, varscan2
- BARX2 | c.776C>A p.A259E | Missense Mutation (SNP) | VAF 20/556 reads (4%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV99858779; called by muse, mutect2
- BIRC2 | c.1706G>T p.R569L | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57162339, COSV99926770; called by muse, mutect2, varscan2
- BMT2 | c.163G>T p.G55* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99774721; called by muse, mutect2, varscan2
- BRDT | c.1044C>G p.C348W | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100746497; called by muse, mutect2, varscan2
- BRSK1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 178/601 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs762289482, COSV58665205; called by muse, mutect2, varscan2
- BRWD1 | c.1927A>C p.N643H | Missense Mutation (SNP) | VAF 82/134 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100313680; called by muse, mutect2, varscan2
- CABP5 | c.522A>T p.*174Cext*31 | Nonstop Mutation (SNP) | VAF 101/262 reads (39%) | catalogued as COSV99506603; called by muse, mutect2, varscan2
- CACNA1B | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV53121283; called by muse, mutect2, varscan2
- CAPN2 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.363); catalogued as rs149659079; called by muse, mutect2, varscan2
- CCT2 | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 115/799 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100167722; called by muse, mutect2, varscan2
- CDC42SE1 | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 66/485 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs1272285984, COSV100603384; called by muse, mutect2, varscan2
- CDCA2 | c.161C>G p.P54R | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99648682; called by muse, mutect2, varscan2
- CEP350 | c.8288T>G p.V2763G | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100854932; called by muse, mutect2, varscan2
- CEP63 | c.793C>G p.L265V | Missense Mutation (SNP) | VAF 54/60 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100132892; called by muse, mutect2, varscan2
- CEP83 | c.1960A>C p.M654L | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51577193, COSV99313427; called by muse, mutect2, varscan2
- CFAP47 | c.4651G>T p.E1551* | Nonsense Mutation (SNP) | VAF 27/40 reads (68%) | catalogued as COSV100545532; called by muse, mutect2, varscan2
- CFH | c.1196A>G p.N399S | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.098); catalogued as COSV100661508; called by muse, mutect2
- CFHR4 | c.1144C>T p.Q382* (on ENST00000367416 / NM_001201551.2; = p.Q136* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 47/194 reads (24%) | catalogued as COSV99260846; called by muse, mutect2, varscan2
- CHD7 | c.5935T>C p.S1979P | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101418323; called by muse, mutect2, varscan2
- CHMP4A | c.664T>C p.S222P | Missense Mutation (SNP) | VAF 244/969 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs1007849983, COSV99841781; called by muse, mutect2, varscan2
- CLK2 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 431/841 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1001352514, COSV100751892; called by mutect2, varscan2
- CLSTN1 | c.1022C>T p.P341L (on ENST00000377298 / NM_001009566.3; = p.P331L on NM_014944.4) | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs573501912, COSV100790674; called by muse, mutect2, varscan2
- COL4A6 | c.4280C>G p.P1427R | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV100564491; called by muse, mutect2, varscan2
- COPS6 | c.367G>T p.G123C | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100385039; called by muse, mutect2, varscan2
- CRISP3 | c.336T>A p.N112K (on ENST00000371159 / NM_001368123.1; = p.N94K on NM_006061.4) | Missense Mutation (SNP) | VAF 67/1240 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99539064; called by muse, mutect2
- CTIF | c.819G>C p.E273D | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV99837912; called by muse, mutect2, varscan2
- CUL9 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 56/1114 reads (5%) | catalogued as COSV99335641; called by muse, mutect2
- DBX1 | c.706T>C p.W236R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99910239; called by muse, mutect2, varscan2
- DDX19B | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 131/415 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV99850048; called by muse, mutect2, varscan2
- DDX55 | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 156/448 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99434653; called by muse, mutect2, varscan2
- DEPDC7 | c.373G>A p.E125K (on ENST00000241051 / NM_001077242.2; = p.E116K on NM_139160.2) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV53807369, COSV99572794; called by muse, mutect2
- DEPDC7 | c.375A>T p.E125D (on ENST00000241051 / NM_001077242.2; = p.E116D on NM_139160.2) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99572796; called by muse, mutect2
- DGKB | c.1016G>T p.C339F | Missense Mutation (SNP) | VAF 101/734 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99341050; called by muse, mutect2, varscan2
- DMRT1 | c.871C>T p.H291Y | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV101206682; called by muse, mutect2, varscan2
- DYM | c.1393G>C p.A465P | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99493534; called by muse, mutect2, varscan2
- EBF1 | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 230/649 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV100566051; called by muse, mutect2, varscan2
- ECHDC1 | c.743G>C p.W248S (on ENST00000531967 / NM_001139510.1; = p.W242S on NM_001002030.2) | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100541808; called by muse, mutect2, varscan2
- ECT2 | c.2698G>C p.E900Q (on ENST00000392692 / NM_001349098.2; = p.E869Q on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.172); catalogued as COSV99221540; called by muse, mutect2
- EP300 | c.4468G>C p.A1490P | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99607497; called by muse, mutect2, varscan2
- ERICH3 | c.2378G>T p.G793V | Missense Mutation (SNP) | VAF 68/408 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs764527597, COSV58605360, COSV58606466; called by muse, varscan2
- ERVW-1 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.39); catalogued as COSV101423850; called by muse, mutect2, varscan2
- EYA2 | c.433C>G p.Q145E | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.438); catalogued as COSV100427086; called by muse, mutect2, varscan2
- F8 | c.5314A>G p.N1772D | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.022); catalogued as COSV100811651; called by muse, mutect2
- FLG2 | c.944C>G p.S315* | Nonsense Mutation (SNP) | VAF 68/439 reads (15%) | catalogued as rs1029358710, COSV101166009; called by muse, mutect2, varscan2
- FSTL5 | c.492A>T p.E164D | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100056664; called by muse, mutect2, varscan2
- GBA2 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 98/536 reads (18%) | catalogued as COSV100803431; called by muse, varscan2
- GLI3 | c.1888A>G p.T630A | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV101229940; called by muse, mutect2, varscan2
- GPATCH3 | c.1029G>C p.Q343H | Missense Mutation (SNP) | VAF 37/260 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100658850; called by muse, mutect2, varscan2
- GPATCH3 | c.1028A>C p.Q343P | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100658852; called by muse, mutect2, varscan2
- HAND2 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs1239151504, COSV64017766; called by muse, mutect2
- HLA-DQB1 | c.318G>C p.E106D | Missense Mutation (SNP) | VAF 124/224 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.194); catalogued as COSV100891298; called by muse, mutect2
- HNRNPUL2 | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100079704; called by muse, mutect2, varscan2
- INSC | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101089368; called by muse, mutect2, varscan2
- KDM4B | c.2085G>T p.Q695H | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99346805; called by muse, mutect2, varscan2
- KIAA0513 | c.432C>G p.R144= | Splice Region (SNP) | VAF 94/248 reads (38%) | catalogued as COSV99261078; called by muse, mutect2, varscan2
- KIFC1 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 775/999 reads (78%) | catalogued as COSV100997115; called by muse, mutect2, varscan2
- KLHL31 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV100911811; called by muse, mutect2, varscan2
- KRT4 | c.738+2T>G p.X246_splice | Splice Site (SNP) | VAF 44/260 reads (17%) | catalogued as COSV99543050; called by muse, mutect2, varscan2
- LIMK1 | c.1770C>G p.D590E | Missense Mutation (SNP) | VAF 55/301 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as COSV100283288; called by muse, mutect2, varscan2
- LRP1 | c.3805C>T p.P1269S | Missense Mutation (SNP) | VAF 133/1497 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99676429; called by muse, mutect2
- LRP6 | c.1625G>A p.G542D | Missense Mutation (SNP) | VAF 187/656 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs139800650; called by muse, mutect2, varscan2
- MAN2C1 | c.2886+2C>A p.X962_splice | Splice Site (SNP) | VAF 15/33 reads (45%) | catalogued as COSV99145545; called by muse, mutect2, varscan2
- MAP3K19 | c.3653G>T p.G1218V | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100208830; called by muse, mutect2, varscan2
- MAP3K6 | c.1759T>G p.C587G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100709302; called by muse, varscan2
- MC1R | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.167); catalogued as rs201028944, COSV100205950; called by muse, mutect2, varscan2
- MTCL1 | c.1217A>C p.K406T (on ENST00000306329 / NM_001378206.1; = p.K46T on NM_015210.4) | Missense Mutation (SNP) | VAF 69/298 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100095056; called by muse, mutect2, varscan2
- MYCN | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55257406, COSV55259752; called by mutect2, varscan2
- MYO15A | c.5737C>T p.L1913F | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99233491; called by muse, mutect2, varscan2
- MYO18B | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs762516694, COSV100124256; called by muse, varscan2
- MYOC | c.1112A>T p.Y371F | Missense Mutation (SNP) | VAF 174/441 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231580; called by muse, mutect2, varscan2
- NAA25 | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs375144860; called by muse, mutect2, varscan2
- NCK1 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99999714; called by muse, mutect2, varscan2
- NPAP1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as rs1049852251, COSV100275650, COSV61510297; called by muse, mutect2, varscan2
- NPS | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as rs1241684674, COSV101219402, COSV67690605; called by muse, mutect2, varscan2
- OLFM1 | c.1018G>A p.G340S (on ENST00000371793 / NM_001282611.2; = p.G322S on NM_014279.5) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759911203, COSV99424050; called by muse, mutect2, varscan2
- OR10T2 | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV100555013; called by muse, mutect2, varscan2
- OR52A5 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.236); catalogued as rs1359981875, COSV100263353, COSV100263497; called by muse, mutect2, varscan2
- OR5K1 | c.653A>T p.Y218F | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773689781, COSV100220992, COSV100221019; called by muse, mutect2, varscan2
- OR5V1 | c.277T>G p.S93A | Missense Mutation (SNP) | VAF 65/340 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV101011360; called by muse, mutect2, varscan2
- OR6S1 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.055); catalogued as COSV100289430; called by muse, mutect2, varscan2
- OR7D4 | c.370G>C p.V124L | Missense Mutation (SNP) | VAF 78/357 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100432791; called by muse, mutect2, varscan2
- OTOF | c.4991C>A p.A1664E (on ENST00000272371 / NM_194248.3; = p.A897E on NM_004802.4) | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV55519537, COSV99718187; called by muse, mutect2, varscan2
- PAPOLB | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101271510; called by muse, mutect2, varscan2
- PDCD11 | c.69C>G p.F23L | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100428275; called by muse, mutect2, varscan2
- PDE11A | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.234); catalogued as rs780940196, COSV53703180; called by muse, mutect2, varscan2
- PEG3 | c.4491G>T p.E1497D | Missense Mutation (SNP) | VAF 193/694 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV99689506; called by muse, mutect2, varscan2
- PFKL | c.857G>C p.R286T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV100827224; called by muse, mutect2, varscan2
- PTHLH | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 46/319 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1463175258, COSV52366518; called by muse, mutect2, varscan2
- RABGEF1 | c.1387C>G p.Q463E (on ENST00000439720 / NM_001287061.2; = p.Q450E on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV53165218; called by muse, mutect2, varscan2
- RAP1GDS1 | c.541G>A p.V181I (on ENST00000408927 / NM_001100427.2; = p.V182I on NM_021159.5) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.498); catalogued as COSV99217128; called by muse, mutect2, varscan2
- REPS1 | c.1615A>G p.T539A (on ENST00000450536 / NM_001286611.2; = p.T538A on NM_031922.4) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs748200886, COSV99238830; called by muse, mutect2, varscan2
- RHOC | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 78/278 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV99588394; called by muse, mutect2, varscan2
- RNF144A | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 54/309 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs898242207; called by muse, mutect2, varscan2
- RNF2 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 43/808 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100835769; called by muse, mutect2
- RORB | c.1170G>T p.R390S (on ENST00000396204 / NM_001365023.1; = p.R379S on NM_006914.4) | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT tolerated (0.86); PolyPhen benign (0.304); catalogued as COSV100974383; called by muse, mutect2, varscan2
- S1PR2 | c.296G>A p.R99K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100495338; called by muse, mutect2, varscan2
- SKAP1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 261/1313 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs761604918, COSV61145889; called by muse, mutect2, varscan2
- SLC39A2 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 45/259 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100068633; called by muse, mutect2, varscan2
- SLC44A5 | c.1235G>T p.C412F | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100902218; called by muse, mutect2, varscan2
- SLCO1A2 | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV100262261; called by muse, mutect2, varscan2
- SLX4 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV99568255; called by muse, mutect2, varscan2
- SMG8 | c.2570G>A p.R857Q | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as rs1439699870, COSV56285274; called by muse, mutect2, varscan2
- TCHHL1 | c.263T>A p.I88K | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100916561; called by muse, mutect2
- TFAP2B | c.389C>G p.P130R | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.261); catalogued as COSV99540469; called by muse, mutect2
- TMEM131 | c.3875A>G p.H1292R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV51780133, COSV99488486; called by muse, mutect2, varscan2
- TNXB | c.12196G>A p.A4066T (on ENST00000647633; = p.A3819T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.95); PolyPhen benign (0.181); catalogued as rs142610250; called by muse, mutect2, varscan2
- TRIM23 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99140109; called by muse, mutect2, varscan2
- TRPA1 | c.697A>G p.N233D | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100084577; called by muse, mutect2, varscan2
- TTC21A | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100073194; called by mutect2, varscan2
- TXLNA | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1285280917, COSV101009885; called by muse, mutect2, varscan2
- UFL1 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV100990097; called by muse, mutect2, varscan2
- UPF2 | c.3597G>C p.W1199C | Missense Mutation (SNP) | VAF 70/517 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV100707340; called by muse, mutect2, varscan2
- USP44 | c.995A>G p.Y332C | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.632); catalogued as COSV99311931; called by muse, mutect2, varscan2
- VILL | c.1438dup p.H480Pfs*38 | Frame Shift Ins (INS) | VAF 14/110 reads (13%) | catalogued as rs753585188; called by mutect2, varscan2
- XIRP2 | c.3436C>G p.L1146V (on ENST00000628543; = p.L1321V on NM_152381.6) | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99744835; called by muse, mutect2, varscan2
- YEATS2 | c.1840C>A p.Q614K | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as COSV100528028; called by muse, mutect2
- ZBED9 | c.476A>G p.D159G | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs769139642, COSV101509316; called by muse, mutect2, varscan2
- ZC3H7B | c.954dup p.A319Rfs*58 | Frame Shift Ins (INS) | VAF 10/74 reads (14%) | catalogued as rs768896328; called by mutect2, pindel
- ZFHX3 | c.9545C>T p.T3182I | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV99213545; called by muse, mutect2, varscan2
- ZFP82 | c.1211G>T p.S404I | Missense Mutation (SNP) | VAF 71/456 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.196); catalogued as COSV101089185; called by muse, mutect2, varscan2
- ZNF28 | c.554A>C p.K185T | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100354565; called by muse, mutect2, varscan2
- ZNF829 | c.245C>G p.A82G | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV101199674; called by muse, mutect2, varscan2
- FAT3 | c.13212A>C p.E4404D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- GPAM | c.146_151del p.L49_K50del | In Frame Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- SLC18A2 | c.280_286del p.R94* | Frame Shift Del (DEL) | VAF 21/142 reads (15%) | called by mutect2, pindel, varscan2
- TEX2 | c.87_88del p.S30Pfs*27 | Frame Shift Del (DEL) | VAF 44/266 reads (17%) | called by pindel, varscan2
- ABCC5 | c.3489C>T p.I1163= | Silent (SNP) | VAF 271/2103 reads (13%) | catalogued as COSV99657149; called by muse, mutect2, varscan2
- ACAD11 | c.1935C>T p.R645= | Silent (SNP) | VAF 33/231 reads (14%) | catalogued as rs143711603; called by muse, mutect2, varscan2
- ADAMTS1 | c.921G>A p.V307= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV53172743; called by muse, mutect2, varscan2
- ADAMTS9 | c.1716C>T p.C572= | Silent (SNP) | VAF 69/342 reads (20%) | catalogued as COSV99899769; called by muse, mutect2, varscan2
- AKAP6 | c.3669C>T p.D1223= | Silent (SNP) | VAF 129/516 reads (25%) | catalogued as COSV99802180; called by muse, mutect2, varscan2
- ANGPTL2 | c.261G>A p.Q87= | Silent (SNP) | VAF 28/150 reads (19%) | catalogued as COSV99401982; called by muse, mutect2, varscan2
- ANKK1 | c.492C>T p.F164= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as rs751094655, COSV58270600; called by muse, mutect2, varscan2
- APOBEC1 | c.150C>T p.I50= | Silent (SNP) | VAF 31/231 reads (13%) | catalogued as COSV99981143; called by muse, mutect2, varscan2
- ARFGEF1 | c.3210T>G p.S1070= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as COSV99143038; called by muse, mutect2, varscan2
- ARHGAP33 | c.2799G>T p.G933= | Silent (SNP) | VAF 43/69 reads (62%) | catalogued as COSV99138916; called by muse, mutect2, varscan2
- ARSH | c.972C>T p.N324= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs894785893, COSV66963241; called by muse, mutect2, varscan2
- B4GALNT1 | c.399T>G p.A133= | Silent (SNP) | VAF 18/270 reads (7%) | catalogued as rs1555186659, COSV100247210; ClinVar: likely benign; called by muse, mutect2
- BEGAIN | c.960G>A p.A320= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100766991; called by muse, mutect2
- BTBD11 | c.2730G>T p.S910= (on ENST00000280758 / NM_001018072.2; = p.S447= on NM_001017523.2) | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV99776273, COSV99776413; called by muse, mutect2, varscan2
- CACNA1D | c.3681C>T p.Y1227= (on ENST00000350061 / NM_001128840.3; = p.Y1247= on NM_000720.4) | Silent (SNP) | VAF 80/316 reads (25%) | catalogued as rs750641374, COSV99858911; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCL11 | c.177G>A p.Q59= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100005620; called by muse, mutect2, varscan2
- CNNM4 | c.1359C>T p.F453= | Silent (SNP) | VAF 26/274 reads (9%) | catalogued as COSV100998729; called by muse, mutect2
- CPVL | c.1297C>A p.R433= | Silent (SNP) | VAF 123/623 reads (20%) | catalogued as rs371059469, COSV99606090; called by muse, mutect2, varscan2
- DNAJC1 | c.1440C>T p.S480= | Silent (SNP) | VAF 33/143 reads (23%) | catalogued as rs61757220, COSV65412668; called by muse, mutect2, varscan2
- F2R | c.861G>T p.T287= | Silent (SNP) | VAF 48/240 reads (20%) | catalogued as COSV59928363; called by muse, mutect2, varscan2
- FRMD4A | c.1563T>A p.S521= | Silent (SNP) | VAF 47/323 reads (15%) | catalogued as COSV99198568; called by muse, mutect2, varscan2
- HIVEP1 | c.4377G>A p.V1459= | Silent (SNP) | VAF 38/218 reads (17%) | catalogued as COSV101045329; called by muse, mutect2, varscan2
- HOOK2 | c.1779G>A p.L593= | Silent (SNP) | VAF 81/299 reads (27%) | catalogued as COSV99317686; called by muse, mutect2, varscan2
- IGF1R | c.1560C>A p.L520= | Silent (SNP) | VAF 110/383 reads (29%) | catalogued as COSV99153346; called by muse, mutect2, varscan2
- ING2 | c.639A>G p.T213= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as rs572463844, COSV100180461; called by muse, mutect2, varscan2
- ITIH5 | c.1089C>T p.H363= | Silent (SNP) | VAF 51/310 reads (16%) | catalogued as COSV99904907; called by muse, mutect2, varscan2
- KIF5B | c.237A>G p.G79= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as COSV100192067; called by muse, mutect2, varscan2
- LAMC3 | c.1398C>T p.T466= | Silent (SNP) | VAF 49/176 reads (28%) | catalogued as rs374312270; called by muse, mutect2, varscan2
- LCT | c.1197A>C p.G399= | Silent (SNP) | VAF 39/254 reads (15%) | catalogued as COSV99929861; called by muse, mutect2, varscan2
- LRRC17 | c.297C>T p.N99= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV99978515; called by muse, mutect2, varscan2
- LRRC43 | c.1083G>T p.L361= | Silent (SNP) | VAF 45/440 reads (10%) | catalogued as COSV100336817; called by muse, mutect2
- MACF1 | c.9474G>A p.S3158= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as rs752005407, COSV99245546; called by muse, mutect2, varscan2
- MUC17 | c.3348T>A p.S1116= | Silent (SNP) | VAF 137/804 reads (17%) | catalogued as COSV100074079, COSV60285181; called by muse, mutect2, varscan2
- MYLK3 | c.324T>A p.G108= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV101189142; called by muse, mutect2, varscan2
- NEB | c.5643C>T p.A1881= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as COSV99425017; called by muse, mutect2, varscan2
- NPFFR2 | c.339A>G p.E113= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV100440950; called by muse, mutect2, varscan2
- NRXN1 | c.1599A>T p.P533= | Silent (SNP) | VAF 166/1004 reads (17%) | catalogued as rs765814415, COSV100455825; called by muse, mutect2, varscan2
- NUP58 | c.519A>T p.G173= | Silent (SNP) | VAF 100/170 reads (59%) | catalogued as COSV101098800; called by muse, mutect2, varscan2
- OR4C15 | c.717G>A p.E239= (on ENST00000314644; = p.E185= on NM_001001920.2) | Silent (SNP) | VAF 22/180 reads (12%) | catalogued as COSV100115834; called by muse, mutect2, varscan2
- PHLDB3 | c.486G>A p.L162= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1307473076, COSV52671010, COSV99415721; called by muse, mutect2, varscan2
- PIM3 | c.681C>T p.T227= | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as rs56188169, COSV100638431; called by muse, mutect2, varscan2
- PLOD2 | c.1417C>A p.R473= | Silent (SNP) | VAF 31/140 reads (22%) | catalogued as COSV51470357, COSV99282962; called by muse, mutect2, varscan2
- PPA1 | c.435T>A p.A145= | Silent (SNP) | VAF 50/211 reads (24%) | catalogued as COSV100949931; called by muse, mutect2, varscan2
- SCN5A | c.4693C>T p.L1565= (on ENST00000333535 / NM_198056.3; = p.L1564= on NM_000335.5) | Silent (SNP) | VAF 80/259 reads (31%) | catalogued as COSV100349288; called by muse, mutect2, varscan2
- SIGLEC9 | c.1050C>G p.V350= | Silent (SNP) | VAF 80/535 reads (15%) | catalogued as COSV99143552; called by muse, mutect2, varscan2
- SLCO4A1 | c.2133C>T p.D711= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99414876; called by muse, mutect2, varscan2
- SNX32 | c.297A>G p.E99= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV100362648; called by muse, mutect2, varscan2
- SQOR | c.804C>T p.A268= | Silent (SNP) | VAF 49/223 reads (22%) | catalogued as rs776263886, COSV99525892; called by muse, mutect2, varscan2
- SRSF5 | c.456C>T p.A152= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs777202427, COSV99384403; called by muse, mutect2, varscan2
- TRAK2 | c.1182C>G p.L394= | Silent (SNP) | VAF 38/228 reads (17%) | catalogued as COSV100216934; called by muse, mutect2, varscan2
- TRIM54 | c.402C>A p.I134= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as COSV99940933; called by muse, mutect2
- TSNARE1 | c.585G>C p.V195= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100210942; called by muse, mutect2, varscan2
- TSPEAR | c.1641C>T p.S547= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV100554435; called by muse, mutect2, varscan2
- TTN | c.25017A>G p.K8339= (on ENST00000591111; = p.K7412= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 110/580 reads (19%) | catalogued as COSV100619835; called by muse, mutect2, varscan2
- VTI1A | c.627G>A p.A209= | Silent (SNP) | VAF 76/293 reads (26%) | catalogued as rs772421699, COSV67581086; called by muse, mutect2, varscan2
- ZNF608 | c.2400C>A p.T800= | Silent (SNP) | VAF 113/429 reads (26%) | catalogued as COSV100102034; called by muse, mutect2, varscan2
- DEPDC7 | c.73+525G>A | Intron (SNP) | VAF 15/73 reads (21%) | catalogued as COSV99572793; called by muse, mutect2, varscan2
- FBXL21P | n.726C>T | RNA (SNP) | VAF 23/107 reads (21%) | catalogued as COSV99778367; called by muse, mutect2, varscan2
- OBSCN | c.11659+4277C>G | Intron (SNP) | VAF 60/1552 reads (4%) | catalogued as COSV99481170; called by muse, mutect2
- RCE1 | c.*2C>G | 3'UTR (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100547130; called by muse, mutect2, varscan2
